TCGA case TCGA-E8-A2JQ — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f69ff5fb-7e0b-4b16-9fc9-498379b11562

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 18 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 18.3 years (6,684 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 356 days; Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Lymph nodes positive: 11; Lymph nodes tested: 14; Measurement unit: Centimeters; Tumor length measurement: 2.1; Tumor width measurement: 1.9.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Levothyroxine Sodium; Days to treatment start: 1 day; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 44 days; Days to treatment end: 44 days; Treatment dose: 144 mCi; Treatment outcome: Complete Response; Number of fractions: 1; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Prescribed dose: 144; Radiosensitizing agent: No.
   Recorded as not given: adjuvant I-131 Radiation Therapy.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Days to follow up: 356 days; Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E8-A2JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-E8-A2JQ-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 0.
- Sample TCGA-E8-A2JQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E8-A2JQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-E8-A2JQ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 500 mg.
  Slide TCGA-E8-A2JQ-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: No; Lymph nodes examined: Yes.
- Follow-up form: Lost to follow-up: Yes; Tumor status: Tumor free; I 131 radiation first treatment method: Patient did not receive I-131 treatment; Radiation therapy xrt sensitizers: No; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: Synthroid.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-01A-11D-A17R-02: DNA aliquot UUID: 4D618B35-B4FB-4030-9F25-AECEADAE7D54 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: EAFFE7A0-3B58-4CCE-A745-8FF8E05DCFD3.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-01A-11D-A17S-01: DNA aliquot UUID: 3B978ABA-D22D-43E4-AC23-62F2BE8CBD54 contains a sample that does not match the genotype for this patient. It has been replaced by DNA aliquot UUID: F30F8F7C-F0E3-4987-8FBB-9C10D5250EBD.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-01A-11D-A17V-08: DNA aliquot UUID: 37BC0DE1-BC03-4EE6-A1B0-B3483743AEEF contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 52299CF0-654E-4A0A-AA9D-DEA3C5F1485C.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-01A-11D-A17Y-05: DNA aliquot UUID: 7ABCD609-6694-43B4-9CB8-660B372C2580 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 2E5CC596-533A-43A1-95DF-343289DED648.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-10A-01D-A17R-02: DNA aliquot UUID: 167F3441-A2D9-45D6-B221-9EF4C45018A3 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 60B04E1E-2889-44E1-94AF-2EED7E43095E.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-10A-01D-A17S-01: DNA aliquot UUID: 22C4FE2C-AAFF-4DD7-BEA8-89830E823606 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 5E0DAA5B-FF19-48BE-A012-9F2386DFC850.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-10A-01D-A17V-08: DNA aliquot UUID: B39ED9C1-A29E-4F35-924B-05298B81CA86 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: CBC0921A-26EE-4492-AF40-BA86D2868EF0.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-11A-11D-A17R-02: DNA aliquot UUID: 809E3DE1-319C-4F73-8FC0-63D01EA09F82 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 362A65B7-3BE1-4B5E-95B0-95895C6E683A.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-11A-11D-A17S-01: DNA aliquot UUID: 5ABC9671-BED1-4E8E-87F0-09E9C0103042 contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: F5A3D4DC-EA96-4225-BAFE-2042CCB44AE1.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-11A-11D-A17V-08: DNA aliquot UUID: C62B06DA-3CD8-4D3D-9D6F-1C193B8398AF contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: 1E2E5415-3EB0-4279-A6CD-AAC232C67B8A.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-E8-A2JQ-11A-11D-A17Y-05: DNA aliquot UUID: 714A3023-B1D5-4E63-9440-E17ADBB8A98F contains a sample that does not match the genotype for this patient. It has been replaced by DNA UUID: A01E6E2A-1051-45D0-B5D1-17B9B9E687D0.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 356 days; disease-specific survival: no event (censored), 356 days; progression-free interval: no event (censored), 356 days.
